Surgical pathology report (de-identified scan), TCGA case TCGA-W3-A824, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  John Wayne Cancer Center, specimen TCGA-W3-A824-06A (Metastatic).

[page 1 of 2]
ICD-O-3

Melanoma, malignant NOS
8720/3

Site: Lymph node, axilla
C77.3

JW 11/21/13

Coll:

Recd:

CLINICAL HISTORY

Metastatic melanoma left axilla.

GROSS DESCRIPTION

1. Labeled "left axillary nodes and contents, suture at apex": The specimen consists of a 531 gram, 19.5 x 15.5 x 5.5 cm segment of soft red and yellow fatty tissue. Attached to one surface is a 12.1 x 6.2 cm ellipse of tan skin bearing a central 3.5 cm long sutured incision. The skin surrounding the incision is focally hemorrhagic and granular. Beneath the incision there is a previously bisected firm tan somewhat lobulated 6.8 x 6.2 x 6.0 cm tumor. A portion of the tumor appears to have been previously removed. Along the apparent deep surface the tumor is covered with an thin layer of red tan tissue measuring less than 0.1 cm in thickness. The deep margin surrounding the tumor focally shows attached red brown muscle. The tumor does not appear to invade the overlying skin, which shows a 3 cm long area of linear retraction which is located 1.6 cm from the sutured incision. Beneath the incision there is hemorrhage and yellow tan fat necrosis adjacent to the tumor. Additional rubbery firm purple tan lymph nodes ranging up to 2.9 cm are found within the soft tissue. Representative sections are submitted as follows: 1A - tumor and overlying skin and closest soft tissue margin; 1B - tumor and overlying skin incision; 1C - tumor and closest soft tissue margin; 1D - lymph node closest to suture, bisected; 1E - seven nodes; 1F - 10 nodes; 1G - six nodes; 1H - five nodes; 1I-1J - one node sectioned; 1K-1L - one lymph node sectioned; 1M-1N - one lymph node sectioned; 1O - two nodes each bisected, one inked blue; 1P - one lymph node sectioned; 1Q - one lymph node sectioned; 1R - two lymph nodes each bisected, one inked blue; 1S - two lymph nodes each bisected, one inked blue; 1T - two lymph nodes each bisected, one inked blue; 1U - two lymph nodes, one inked blue and not sectioned, one uninked and sectioned.

2. Labeled "skin lesion left chest wall, rule out in transit metastasis": The specimen

[page 2 of 2]
consists of a 0.4 x 0.1 x 0.1 cm pink tan tissue fragment. Totally submitted in 2A.

Microscopic sections are prepared and interpreted.

DIAGNOSIS

1. ✓ LEFT AXILLARY LYMPH NODES AND AXILLARY CONTENTS.
- BULKY METASTASIS OF MALIGNANT MELANOMA (6.8 CM DIAMETER) COMPLETELY REPLACING ONE LYMPH NODE.
- MALIGNANT MELANOMA EXTENDS BEYOND LYMPH NODE CAPSULE INTO SOFT TISSUE OF AXILLA AND INTO DERMIS OF AXILLARY SKIN.
- METASTATIC MALIGNANT MELANOMA WITHIN 2 OF 44 ADDITIONAL LEFT AXILLARY LYMPH NODES.
- BIOPSY SITE REACTION AND SKIN SCAR.
- AJCC PATHOLOGIC STAGE T2 N2a (STAGE III).
2. SKIN BIOPSY OF LEFT CHEST WALL.
- BENIGN CAPILLARY HEMANGIOMA.
- NEGATIVE FOR MALIGNANCY.

ADDENDUM

** ADDENDUM NO.1 **

Please see attached report from dated

Signed Electronically signed by:

** END OF REPORT **

HI/FAA Discrepancy		✓

Source: NCI Genomic Data Commons file 50651605-3ddf-4d26-8cc6-672b09811515 (TCGA-W3-A824.E8E86625-8D7E-419F-A4BB-86499B9E4E88.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).